Somatic mutation profile of tumor specimen ALCH-B2U1-TTP1-A (aliquot ALCH-B2U1-TTP1-A-1-0-D-A78Q-36) from ALCHEMIST case ALCH-B2U1, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 73.6 years (26,897 days).
Specimen ALCH-B2U1-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 839bc015-7ddd-4a17-baf6-dbfca2cc71d9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2U1-NB1-A (Blood Derived Normal), aliquot ALCH-B2U1-NB1-A-1-0-D-A78Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/720f1bf9-d0d0-40a6-8fe2-7a829b6a6d4d

The open-access MAF lists 54 somatic variants for this specimen: 38 protein-altering or splice-affecting, 12 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 12, Intron 3, Frame Shift Del 3, Nonsense Mutation 2, Frame Shift Ins 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A2ML1 | c.3116del p.A1039Gfs*49 | Frame Shift Del (DEL) | VAF 10/52 reads (19%) | catalogued as COSV55285108; called by mutect2, pindel
- ACP4 | c.55C>G p.L19V | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.051); catalogued as COSV54517618; called by mutect2, varscan2
- EGFR | c.2335G>T p.G779C | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs397517119, COSV51767677, COSV51852379; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EGFR | c.2336G>T p.G779V | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs397517120, COSV51772282; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIF13B | c.4250C>G p.T1417S | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV104435496; called by muse, mutect2, varscan2
- LRPPRC | c.3326G>A p.R1109H | Missense Mutation (SNP) | VAF 22/332 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.13); catalogued as rs770133754, COSV53233486; called by muse, mutect2
- NUP210L | c.2084C>T p.A695V | Missense Mutation (SNP) | VAF 24/444 reads (5%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs780700424, COSV55158210; called by muse, mutect2
- PDE2A | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs779033222, COSV57814123; called by muse, mutect2, varscan2
- SLC4A3 | c.2731C>T p.R911C | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1444311990, COSV56093013; called by muse, mutect2
- TTN | c.28367C>A p.A9456E (on ENST00000591111; = p.A8529E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/283 reads (5%) | PolyPhen probably damaging (0.998); catalogued as COSV60157689; called by muse, mutect2
- UPF3B | c.1102C>T p.R368W (on ENST00000276201 / NM_080632.3; = p.R355W on NM_023010.3) | Missense Mutation (SNP) | VAF 11/158 reads (7%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.858); catalogued as rs374676402, COSV52230481; called by muse, mutect2
- A2M | c.2452C>G p.L818V | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, varscan2
- ACAD10 | c.1651A>G p.M551V | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ADRB2 | c.897G>T p.Q299H | Missense Mutation (SNP) | VAF 117/573 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP8B3 | c.830A>T p.N277I | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- CCDC191 | c.91C>A p.P31T | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.127); called by muse, mutect2
- CHM | c.147T>G p.S49R | Missense Mutation (SNP) | VAF 21/509 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- DHRS4 | c.381G>A p.M127I | Missense Mutation (SNP) | VAF 16/264 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2
- EEF1E1 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 20/528 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.764); called by muse, mutect2
- EYS | c.1333T>A p.C445S | Missense Mutation (SNP) | VAF 22/510 reads (4%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2
- IL33 | c.707C>T p.P236L | Missense Mutation (SNP) | VAF 33/433 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.659); called by muse, mutect2
- IQCD | c.524G>T p.G175V | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0.009); called by muse, mutect2
- LRRK2 | c.2282dup p.L761Ffs*4 | Frame Shift Ins (INS) | VAF 34/261 reads (13%) | called by mutect2, pindel, varscan2
- LYST | c.7812A>T p.E2604D | Missense Mutation (SNP) | VAF 36/562 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- MCCC1 | c.1481A>G p.K494R | Missense Mutation (SNP) | VAF 56/330 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MPP6 | c.1146del p.D383Mfs*59 | Frame Shift Del (DEL) | VAF 47/279 reads (17%) | called by mutect2, pindel, varscan2
- MSH4 | c.20C>G p.S7* | Nonsense Mutation (SNP) | VAF 3/28 reads (11%) | called by muse, mutect2
- NLRP3 | c.694A>G p.I232V | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.417); called by muse, mutect2
- OGDHL | c.1409T>A p.V470E | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PAPPA2 | c.3846G>T p.L1282F | Missense Mutation (SNP) | VAF 14/221 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); called by muse, mutect2
- PTPRD | c.5576T>A p.I1859N | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- RNASEH2B | c.776A>C p.K259T | Missense Mutation (SNP) | VAF 45/311 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- SETD2 | c.355G>T p.E119* | Nonsense Mutation (SNP) | VAF 17/184 reads (9%) | called by muse, mutect2
- SLC29A3 | c.1336G>A p.A446T | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- SPATA31A6 | c.1025A>C p.E342A | Missense Mutation (SNP) | VAF 40/678 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.03); called by muse, mutect2
- TP53 | c.740_753del p.N247Tfs*12 | Frame Shift Del (DEL) | VAF 16/123 reads (13%) | called by mutect2, pindel, varscan2
- VEGFB | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.023); called by mutect2, varscan2
- ZNF668 | c.1337dup p.A447Gfs*61 | Frame Shift Ins (INS) | VAF 4/26 reads (15%) | called by mutect2, varscan2
- ARMCX5-GPRASP2 | c.1269A>G p.Q423= | Silent (SNP) | VAF 13/62 reads (21%) | called by muse, mutect2, varscan2
- CHM | c.552T>C p.D184= | Silent (SNP) | VAF 15/322 reads (5%) | called by muse, mutect2
- CLTC | c.3180C>T p.I1060= | Silent (SNP) | VAF 8/240 reads (3%) | called by muse, mutect2
- COL4A6 | c.3582C>T p.T1194= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as rs370164057, COSV100564982; called by muse, mutect2, varscan2
- FXR1 | c.309C>T p.Y103= | Silent (SNP) | VAF 39/292 reads (13%) | called by muse, mutect2, varscan2
- HBG2 | c.252C>T p.G84= | Silent (SNP) | VAF 41/662 reads (6%) | catalogued as rs748286620, COSV57963608; called by muse, mutect2
- HOXA2 | c.693G>A p.T231= | Silent (SNP) | VAF 18/94 reads (19%) | catalogued as rs746566874; called by muse, mutect2, varscan2
- PON3 | c.36C>T p.V12= | Silent (SNP) | VAF 17/168 reads (10%) | catalogued as rs930141482; called by muse, mutect2
- QDPR | c.564G>C p.P188= | Silent (SNP) | VAF 24/278 reads (9%) | called by muse, mutect2
- RAG1 | c.1203G>A p.S401= | Silent (SNP) | VAF 24/352 reads (7%) | catalogued as rs753446485, COSV55026194; called by muse, mutect2
- STX19 | c.423C>T p.F141= | Silent (SNP) | VAF 11/184 reads (6%) | catalogued as rs1415635215; called by muse, mutect2
- TENM2 | c.3180C>T p.I1060= (on ENST00000518659 / NM_001122679.2; = p.I828= on NM_001080428.3) | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as rs374408633; called by mutect2, varscan2
- AC008676.3 | c.-2232-21693C>G | Intron (SNP) | VAF 5/29 reads (17%) | called by muse, mutect2, varscan2
- ASCC1 | c.-33-9A>G | Intron (SNP) | VAF 67/348 reads (19%) | called by muse, mutect2, varscan2
- SEC14L1 | c.2042+191C>T | Intron (SNP) | VAF 15/143 reads (10%) | catalogued as rs1172982309; called by muse, mutect2, varscan2
- XIAP | c.*5011C>T | 3'UTR (SNP) | VAF 87/313 reads (28%) | called by muse, mutect2, varscan2
